Somatic mutation profile of tumor specimen TCGA-2L-AAQM-01A (aliquot TCGA-2L-AAQM-01A-11D-A397-08) from TCGA case TCGA-2L-AAQM, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 52.9 years (19,315 days).
Specimen TCGA-2L-AAQM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b7b964a-e8c4-4d17-8dd8-cf86a5eddeed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2L-AAQM-11A (Solid Tissue Normal), aliquot TCGA-2L-AAQM-11A-11D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e42cd2d-a7fa-47f2-93f0-7ad79118e51e

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Frame Shift Del 3, Splice Site 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QTNF1 | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100189672; called by muse, mutect2
- CA5A | c.816A>C p.E272D | Missense Mutation (SNP) | VAF 58/66 reads (88%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV99990317; called by muse, mutect2, varscan2
- CDC42BPG | c.4000G>A p.E1334K | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769055544, COSV61349024; called by muse, mutect2, varscan2
- COL5A3 | c.3562A>G p.T1188A | Missense Mutation (SNP) | VAF 287/593 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99318018; called by muse, mutect2, varscan2
- CORIN | c.1282T>A p.C428S | Missense Mutation (SNP) | VAF 17/490 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV99902643; called by muse, mutect2
- CRNKL1 | c.2174A>G p.E725G | Missense Mutation (SNP) | VAF 213/440 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs111503447, COSV100131415; called by muse, mutect2, varscan2
- DACH2 | c.1101A>G p.I367M | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100912313; called by muse, mutect2, varscan2
- DNAH8 | c.1634C>A p.P545Q | Missense Mutation (SNP) | VAF 121/139 reads (87%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as rs199804814, COSV100542729; called by muse, mutect2, varscan2
- EIF3A | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 81/380 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100974451; called by muse, mutect2, varscan2
- EPC1 | c.1953G>C p.L651F | Missense Mutation (SNP) | VAF 117/137 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99552468; called by muse, mutect2, varscan2
- ESRRB | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 103/210 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755315466, COSV55059918; called by muse, mutect2, varscan2
- FRYL | c.357G>C p.R119S | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99975322; called by muse, mutect2
- HSD17B7 | c.536T>G p.F179C | Missense Mutation (SNP) | VAF 114/130 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1340032718, COSV99597505; called by muse, mutect2, varscan2
- LRRC42 | c.707C>A p.T236K | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100066208; called by muse, mutect2, varscan2
- MEN1 | c.840-2A>G p.X280_splice | Splice Site (SNP) | VAF 80/93 reads (86%) | catalogued as CS973732, COSV53642267, COSV99580082; called by muse, mutect2, varscan2
- PBRM1 | c.3820T>G p.L1274V (on ENST00000296302 / NM_001366071.2; = p.L1249V on NM_018313.5) | Missense Mutation (SNP) | VAF 66/291 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99966818; called by muse, mutect2, varscan2
- PHLDB2 | c.3391C>T p.H1131Y (on ENST00000393925 / NM_001134439.2; = p.H1088Y on NM_145753.2) | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101208327; called by muse, mutect2, varscan2
- PTGES | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs200179410, COSV61393589; called by muse, varscan2
- RIN2 | c.1021A>G p.S341G (on ENST00000255006 / NM_001242581.1; = p.S292G on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.143); catalogued as COSV99656506; called by muse, mutect2, varscan2
- SRP9 | c.131A>T p.D44V | Missense Mutation (SNP) | VAF 94/135 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100504827; called by muse, mutect2, varscan2
- TMEM26 | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.167); catalogued as rs1348590552, COSV53262470, COSV99515386; called by muse, mutect2
- ZNF224 | c.1653G>A p.W551* | Nonsense Mutation (SNP) | VAF 136/538 reads (25%) | catalogued as COSV100425288; called by muse, mutect2, varscan2
- AMPD1 | c.2018_2037del p.K673Ifs*4 | Frame Shift Del (DEL) | VAF 70/115 reads (61%) | called by mutect2, pindel, varscan2
- HNF1B | c.1230G>T p.L410F | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPEN | c.5196_5202del p.A1733Lfs*15 | Frame Shift Del (DEL) | VAF 122/736 reads (17%) | called by mutect2, pindel, varscan2
- ZSCAN16 | c.798_802del p.C266* | Frame Shift Del (DEL) | VAF 151/192 reads (79%) | called by mutect2, pindel, varscan2
- APOL4 | c.558G>A p.G186= (on ENST00000352371 / NM_145660.2; = p.G183= on NM_030643.4) | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs370797006; called by muse, mutect2, varscan2
- CACNA1B | c.1830C>A p.I610= | Silent (SNP) | VAF 63/149 reads (42%) | catalogued as COSV99494493; called by muse, mutect2, varscan2
- ERBIN | c.390C>A p.L130= | Silent (SNP) | VAF 134/721 reads (19%) | catalogued as COSV99395604; called by muse, mutect2, varscan2
- FUT6 | c.681C>T p.P227= | Silent (SNP) | VAF 80/760 reads (11%) | catalogued as COSV54610094; called by muse, mutect2, varscan2
- LAMA2 | c.8757T>A p.P2919= | Silent (SNP) | VAF 63/525 reads (12%) | catalogued as COSV101369841; called by muse, mutect2, varscan2
- PITPNM2 | c.2952G>A p.K984= | Silent (SNP) | VAF 31/954 reads (3%) | catalogued as rs1162779576, COSV99758073; called by muse, mutect2
- TLL1 | c.1152G>T p.G384= | Silent (SNP) | VAF 138/310 reads (45%) | catalogued as rs746750970, COSV99285629; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826265 G>A | 3'Flank (SNP) | VAF 18/449 reads (4%) | called by muse, mutect2
